Somatic mutation profile of tumor specimen TCGA-92-7340-01E (aliquot TCGA-92-7340-01E-01D-A38P-08) from TCGA case TCGA-92-7340, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.0 years (16,447 days).
Specimen TCGA-92-7340-01E: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69d42128-7284-4126-972d-27582c0b1a08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-7340-10A (Blood Derived Normal), aliquot TCGA-92-7340-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8d88ec4-092e-485b-bfc8-122855c91ef1

The open-access MAF lists 313 somatic variants for this specimen: 227 protein-altering or splice-affecting, 77 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 77, Nonsense Mutation 11, Frame Shift Del 5, Splice Site 4, Splice Region 3, RNA 3, Intron 3, Frame Shift Ins 2, 5'Flank 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.629); catalogued as rs567588953, COSV55960138, COSV99789346; called by muse, mutect2, varscan2
- ABCA6 | c.4579A>T p.I1527F | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99446214; called by muse, mutect2, varscan2
- ABCE1 | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV99668503; called by muse, mutect2, varscan2
- ADGRB3 | c.3486G>C p.L1162F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV53234959, COSV99484492; called by muse, mutect2, varscan2
- ADGRL1 | c.2959C>T p.R987C (on ENST00000340736 / NM_001008701.3; = p.R982C on NM_014921.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1329892867, COSV100529345; called by muse, mutect2, varscan2
- AFF3 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as rs781704362, COSV57839916; called by muse, mutect2, varscan2
- AMER1 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748618414, COSV100365809; called by mutect2, varscan2
- ANXA13 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 23/201 reads (11%) | catalogued as rs766941266, COSV51627094; called by muse, mutect2, varscan2
- AOC2 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99513579; called by muse, mutect2, varscan2
- APBB1IP | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as COSV100882007; called by muse, mutect2, varscan2
- AR | c.1984G>T p.V662L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV65964072, COSV65965216; called by muse, mutect2, varscan2
- ARFGEF1 | c.4990G>A p.D1664N | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV99141796; called by muse, mutect2, varscan2
- ARGFX | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); catalogued as COSV100544101; called by muse, mutect2, varscan2
- ARHGAP29 | c.3630C>G p.D1210E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780996785, COSV99557948; called by mutect2, varscan2
- ASB4 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99987132; called by muse, mutect2, varscan2
- ASCC2 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 31/231 reads (13%) | catalogued as COSV100316172, COSV100316331; called by muse, mutect2, varscan2
- ASPHD2 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs1250165420, COSV99313254; called by muse, mutect2, varscan2
- ASTN1 | c.1972G>C p.G658R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99921071; called by muse, mutect2, varscan2
- ATMIN | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.051); catalogued as COSV100214572; called by muse, mutect2, varscan2
- ATP10A | c.3789G>T p.W1263C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100791064, COSV63520914; called by muse, mutect2, varscan2
- ATP1B1 | c.97+1G>T p.X33_splice | Splice Site (SNP) | VAF 3/16 reads (19%) | catalogued as rs879113954, COSV100891619; called by muse, mutect2
- ATP2C1 | c.2185C>G p.L729V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371236506; called by mutect2, varscan2
- BRINP2 | c.1807A>T p.M603L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100837978; called by muse, mutect2, varscan2
- C10orf90 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52958706; called by muse, mutect2, varscan2
- C5 | c.4240G>T p.E1414* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV56326132, COSV99797588; called by muse, mutect2, varscan2
- C8orf37 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs768222931, COSV99713106; called by muse, mutect2, varscan2
- CA10 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99562395; called by muse, mutect2, varscan2
- CCDC127 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99722937; called by muse, mutect2, varscan2
- CCDC92 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99435417; called by muse, varscan2
- CCDC92 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99435420; called by muse, varscan2
- CDH18 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 36/123 reads (29%) | catalogued as COSV99933587; called by muse, mutect2, varscan2
- CDH9 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50375363, COSV99142888; called by muse, mutect2, varscan2
- CDYL | c.808C>G p.P270A (on ENST00000328908 / NM_001368125.1; = p.P216A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV100189098; called by mutect2, varscan2
- CFAP69 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100289982; called by muse, mutect2, varscan2
- CFTR | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50075296, COSV99135131, COSV99135516; called by mutect2, varscan2
- CHRD | c.889G>C p.V297L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV99200330; called by muse, mutect2, varscan2
- CHRDL2 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1193510812, COSV99733677; called by muse, mutect2, varscan2
- CLEC4F | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV99713672, COSV99713850; called by muse, mutect2, varscan2
- COL26A1 | c.173A>T p.H58L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV100561631; called by muse, mutect2, varscan2
- CPAMD8 | c.5793G>C p.L1931F (on ENST00000651564; = p.L1884F on NM_015692.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.192); catalogued as COSV50186141; called by muse, mutect2
- CR1L | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as COSV99687069; called by mutect2, varscan2
- CRYBA1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as COSV99836984; called by muse, mutect2, varscan2
- CSMD3 | c.10331T>C p.L3444S (on ENST00000297405 / NM_001363185.1; = p.L3275S on NM_052900.3) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830633; called by muse, mutect2, varscan2
- CSMD3 | c.2015A>T p.Y672F (on ENST00000297405 / NM_001363185.1; = p.Y568F on NM_052900.3) | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); catalogued as COSV99830637; called by muse, mutect2
- DGKI | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933422; called by muse, mutect2, varscan2
- DMBT1 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963526763, COSV100352650, COSV100352669; called by muse, mutect2, varscan2
- DNAH5 | c.2177A>G p.Q726R | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99447903; called by muse, mutect2, varscan2
- DPF3 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.575); catalogued as COSV100818487; called by muse, mutect2, varscan2
- ERCC6L | c.2349G>T p.E783D | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100559068; called by muse, mutect2, varscan2
- FLG | c.5480C>A p.S1827Y | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs1361375721, COSV100911399; called by muse, mutect2
- FRMPD4 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV101042593, COSV66217632; called by muse, mutect2, varscan2
- GALNTL5 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755106841, COSV101217753; called by mutect2, varscan2
- GIMAP2 | c.972G>T p.L324F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs550393647; called by mutect2, varscan2
- GNL3L | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100328261; called by muse, mutect2, varscan2
- GPR182 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs753318249, COSV100267679; called by mutect2, varscan2
- GRIP1 | c.2945T>G p.V982G (on ENST00000359742 / NM_001379345.1; = p.V930G on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV99668947; called by muse, mutect2
- GRIP1 | c.1724A>T p.K575M (on ENST00000359742 / NM_001379345.1; = p.K523M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99668951; called by muse, mutect2, varscan2
- GSTA3 | c.590T>C p.F197S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99274490; called by muse, mutect2, varscan2
- HCN1 | c.2285C>A p.T762K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.081); catalogued as COSV100299634, COSV57491554; called by muse, mutect2, varscan2
- HDLBP | c.2184C>A p.F728L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV100190289; called by muse, varscan2
- HFM1 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99645799; called by muse, mutect2, varscan2
- HS6ST3 | c.1132C>A p.Q378K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100940321, COSV65002569; called by muse, mutect2, varscan2
- IDI2 | c.22T>A p.W8R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99479169; called by muse, mutect2, varscan2
- IFT122 | c.1114G>T p.V372F (on ENST00000348417 / NM_052989.3; = p.V313F on NM_018262.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99959077; called by mutect2, varscan2
- IGSF9 | c.1862C>T p.P621L (on ENST00000368094 / NM_001135050.2; = p.P605L on NM_020789.4) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs546681175, COSV63639444; called by muse, mutect2, varscan2
- IL13RA1 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100861707; called by muse, mutect2, varscan2
- IMPA1 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1313019644, COSV56273587, COSV99808887; called by muse, mutect2, varscan2
- INSR | c.3722C>G p.S1241C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57168748; called by muse, varscan2
- KAT7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52013705; called by muse, mutect2, varscan2
- KCNH7 | c.3162G>T p.Q1054H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1287295418, COSV100147412, COSV59788657; called by muse, mutect2, varscan2
- KEAP1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV50260706, COSV99407609; called by muse, mutect2, varscan2
- KHDRBS2 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV55468078, COSV99832645; called by muse, mutect2
- KHSRP | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231171; called by muse, mutect2, varscan2
- KIAA0319 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.165); catalogued as COSV65500783; called by mutect2, varscan2
- KIF21B | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1200416395, COSV59758331; called by muse, mutect2, varscan2
- KIF26A | c.2015A>G p.K672R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1489038183, COSV100181014; called by muse, mutect2, varscan2
- KL | c.1599A>T p.Q533H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV101199068; called by muse, mutect2, varscan2
- KRT33B | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs553797257, COSV99290550; called by muse, mutect2
- LAMA2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV101370330; called by mutect2, varscan2
- LDAH | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99425505; called by muse, mutect2, varscan2
- LIN7B | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as COSV99674426; called by muse, mutect2
- LRP1B | c.6119C>A p.A2040E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV101255037; called by muse, mutect2
- LRRC40 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs757402855, COSV100918736; called by mutect2, varscan2
- LRRC7 | c.964G>C p.D322H (on ENST00000651989 / NM_001370785.2; = p.D289H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50496995, COSV50601277; called by muse, mutect2, varscan2
- LRRTM3 | c.1666A>T p.T556S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); catalogued as COSV100791577; called by muse, mutect2, varscan2
- MAPKAP1 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as COSV99784655; called by muse, mutect2, varscan2
- MCF2 | c.1365G>C p.G455= | Splice Region (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100644665; called by muse, mutect2
- MEF2B | c.676-1G>C p.X226_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99364535; called by muse, mutect2, varscan2
- MEN1 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99580691; called by muse, mutect2, varscan2
- MGAT2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs372538664; called by mutect2, varscan2
- MKI67 | c.9743G>C p.R3248T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100896389; called by muse, mutect2, varscan2
- MMAA | c.885G>T p.L295F | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99849744; called by muse, mutect2, varscan2
- MMP20 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199788797, COSV99497577; called by muse, mutect2, varscan2
- MMRN2 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100922546; called by muse, mutect2, varscan2
- MTHFD2 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs374942985; called by muse, mutect2, varscan2
- MUC16 | c.35516C>T p.A11839V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.013); catalogued as rs777142957, COSV101199315; called by mutect2, varscan2
- MUC16 | c.21458C>T p.P7153L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); catalogued as rs1289597761, COSV101199316; called by muse, mutect2, varscan2
- MUC7 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100512246; called by muse, mutect2, varscan2
- MYH1 | c.1146A>T p.E382D | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99875481; called by muse, mutect2, varscan2
- MYH15 | c.2199G>T p.R733S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842879; called by muse, mutect2, varscan2
- MYH2 | c.4166C>G p.T1389R | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99819800; called by muse, mutect2, varscan2
- NCOR2 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1333540307, COSV100657137; called by muse, mutect2, varscan2
- NDC1 | c.766A>T p.R256W | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99323477; called by muse, mutect2, varscan2
- NDST3 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99630129; called by muse, mutect2, varscan2
- NELL2 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1379064978, COSV100419265; called by muse, mutect2, varscan2
- NLRP4 | c.2701G>T p.E901* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100016027, COSV56707914; called by muse, mutect2, varscan2
- NLRP5 | c.2201G>T p.R734L | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101173528, COSV66762506, COSV66765656; called by muse, mutect2, varscan2
- NME8 | c.569C>G p.T190R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149877831; called by mutect2, varscan2
- NPR2 | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100709425; called by muse, mutect2, varscan2
- NSUN3 | c.129A>G p.I43M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV100113199; called by muse, mutect2, varscan2
- OBSCN | c.20366C>T p.S6789F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs755643834, COSV100802984; called by muse, varscan2
- OLFM3 | c.1173G>C p.K391N (on ENST00000338858 / NM_001288821.1; = p.K371N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100129195; called by muse, mutect2, varscan2
- OR10AG1 | c.106A>T p.I36L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs1328227884, COSV56632248; called by muse, mutect2, varscan2
- OR10T2 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100554912; called by muse, mutect2, varscan2
- OR12D2 | c.-1G>A | Splice Region (SNP) | VAF 47/251 reads (19%) | catalogued as COSV101011196; called by muse, mutect2, varscan2
- OR2B3 | c.364A>T p.R122* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV101013772; called by muse, mutect2, varscan2
- OR2T1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs1244611327, COSV100822285; called by muse, mutect2, varscan2
- OR4C46 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as COSV100060581; called by muse, mutect2, varscan2
- OR4D2 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101613849; called by muse, mutect2, varscan2
- OR51M1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1204694306, COSV60784013, COSV60784470; called by muse, mutect2, varscan2
- OR52E6 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100259257; called by muse, mutect2, varscan2
- OR5H15 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100736645; called by muse, mutect2, varscan2
- OR5M1 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs772373306, COSV101591549, COSV73201989; called by mutect2, varscan2
- OR6F1 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100129084; called by muse, mutect2, varscan2
- PABPC5 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs977990721, COSV100442254; called by muse, mutect2, varscan2
- PANX1 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs577336224, COSV99921744; called by muse, mutect2, varscan2
- PAQR3 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99785003; called by muse, mutect2, varscan2
- PARP9 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs751697051, COSV100831059; called by mutect2, varscan2
- PCDHA4 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100793299; called by muse, mutect2, varscan2
- PCDHA5 | c.1214C>G p.S405W | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100972210; called by muse, mutect2, varscan2
- PCDHA7 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.039); catalogued as COSV100971366; called by muse, mutect2, varscan2
- PCDHB3 | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50574236, COSV99166875; called by muse, mutect2, varscan2
- PCF11 | c.2708G>C p.R903T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100018103; called by mutect2, varscan2
- PDE1C | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV100371999; called by muse, mutect2, varscan2
- PDE1C | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.717); catalogued as COSV101275457, COSV68819282; called by mutect2, varscan2
- PDZD2 | c.4015G>T p.V1339F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs759372157, COSV56864889, COSV99224543; called by mutect2, varscan2
- PEG3 | c.3709A>T p.S1237C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99688318; called by muse, mutect2, varscan2
- PEG3 | c.1984T>A p.C662S | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); catalogued as COSV55645754, COSV99688320; called by muse, mutect2, varscan2
- PHC3 | c.1819G>C p.D607H (on ENST00000494943 / NM_001308116.2; = p.D619H on NM_024947.4) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV101520150; called by muse, mutect2, varscan2
- PKHD1 | c.9591G>C p.Q3197H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs1421251307, COSV100582391; called by muse, mutect2, varscan2
- PLSCR1 | c.296T>C p.L99S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678344; called by muse, mutect2, varscan2
- PLXNA2 | c.3505C>A p.L1169I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV100885311; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100982442; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1642T>C p.Y548H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1363112595, COSV99461127; called by muse, mutect2, varscan2
- PPAT | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as rs756567329, COSV99947170; called by muse, varscan2
- PPP2CA | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99196033; called by muse, mutect2, varscan2
- PROX1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as COSV99799057; called by muse, mutect2, varscan2
- PRRC2A | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100784550; called by muse, mutect2, varscan2
- PRSS16 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100041892; called by muse, mutect2, varscan2
- PSG3 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100548840; called by muse, mutect2
- PSKH1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs768583092, COSV99344578; called by mutect2, varscan2
- PTPRO | c.2770G>C p.D924H (on ENST00000281171 / NM_030667.3; = p.D896H on NM_002848.4) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99840231; called by muse, mutect2, varscan2
- RBMS2 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV100008457, COSV56266017; called by muse, mutect2, varscan2
- REL | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.395); catalogued as COSV99691990; called by muse, mutect2, varscan2
- RGS22 | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1221418331, COSV100693141, COSV100693878; called by muse, mutect2, varscan2
- ROBO1 | c.3322G>T p.E1108* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV71399989; called by mutect2, varscan2
- RUSC1 | c.2248C>G p.L750V (on ENST00000368352 / NM_001105203.2; = p.L281V on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.753); catalogued as COSV99429659; called by muse, mutect2, varscan2
- RYR1 | c.4331C>A p.P1444H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615353; called by muse, mutect2, varscan2
- SAFB2 | c.2296C>A p.H766N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV99385586; called by muse, mutect2, varscan2
- SALL4 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99409386; called by mutect2, varscan2
- SCGB2A1 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV99793720; called by muse, mutect2, varscan2
- SEPTIN10 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61779959; called by muse, mutect2, varscan2
- SERPINI2 | c.247+1G>A p.X83_splice | Splice Site (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99247802; called by muse, mutect2
- SLC17A6 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV54141358, COSV99581204; called by muse, mutect2, varscan2
- SLC27A3 | c.351G>C p.W117C | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV99669873; called by muse, mutect2, varscan2
- SLC2A3 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs201737691, COSV50002302, COSV50003055; called by mutect2, varscan2
- SLC35G1 | c.456G>C p.Q152H (on ENST00000427197 / NM_001134658.3; = p.Q151H on NM_153226.4) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV101004045; called by muse, mutect2, varscan2
- SLC38A6 | c.115A>T p.R39* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV99712050; called by muse, mutect2, varscan2
- SLC46A3 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99906211; called by muse, mutect2, varscan2
- SLC4A9 | c.1920C>A p.F640L (on ENST00000507527 / NM_001258428.2; = p.F616L on NM_031467.3) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99138636; called by muse, mutect2, varscan2
- SLC5A7 | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99886521; called by muse, mutect2, varscan2
- SLC6A16 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1368765660, COSV100242664; called by mutect2, varscan2
- SLC7A3 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV53228660; called by muse, mutect2, varscan2
- SLC9B2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100293969; called by muse, mutect2, varscan2
- SMARCB1 | c.96G>A p.V32= | Splice Region (SNP) | VAF 33/173 reads (19%) | catalogued as COSV99575134; called by muse, mutect2, varscan2
- SMG5 | c.1243A>T p.S415C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV100700758; called by muse, mutect2, varscan2
- SPATA17 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs540164939, COSV65122087; called by muse, mutect2, varscan2
- STARD6 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1257511221, COSV100323399; called by muse, mutect2, varscan2
- STEAP1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs758880644, COSV99787596; called by mutect2, varscan2
- STON1 | c.2185A>G p.I729V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1370891963, COSV100561698; called by muse, mutect2, varscan2
- SYNE1 | c.21814A>G p.K7272E (on ENST00000367255 / NM_182961.4; = p.K7201E on NM_033071.3) | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99559310; called by muse, mutect2
- SYNE1 | c.10700C>G p.A3567G (on ENST00000367255 / NM_182961.4; = p.A3574G on NM_033071.3) | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99559317; called by muse, mutect2, varscan2
- SYNE2 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100420118; called by muse, mutect2, varscan2
- SYNE2 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100420120; called by muse, mutect2
- SZT2 | c.6262C>T p.R2088* (on ENST00000634258 / NM_001365999.1; = p.R2031* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100987051; called by muse, mutect2, varscan2
- TANC1 | c.2396C>A p.S799Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99713538, COSV99715071; called by muse, mutect2, varscan2
- TBX19 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM014745, COSV100892342; called by muse, mutect2, varscan2
- TBX22 | c.249C>G p.S83R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV100960718; called by muse, mutect2, varscan2
- TDRD5 | c.764T>A p.M255K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99675919; called by muse, mutect2, varscan2
- TFEB | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs745674792, COSV100026106; called by muse, mutect2
- TM4SF1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as rs746963430, COSV59525444, COSV59525888; called by muse, mutect2, varscan2
- TMEM89 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140040188; called by muse, mutect2, varscan2
- TMX3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100218303; called by muse, mutect2, varscan2
- TNKS | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.941); catalogued as COSV100126633; called by muse, mutect2, varscan2
- TP53 | c.132del p.M44Ifs*79 | Frame Shift Del (DEL) | VAF 60/222 reads (27%) | catalogued as COSV53759087; called by mutect2, pindel, varscan2
- TRA2B | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs764180360, COSV99373232; called by mutect2, varscan2
- TRIM42 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV99648222, COSV99648902; called by muse, mutect2
- TTN | c.79781C>A p.A26594D (on ENST00000591111; = p.A19170D on NM_003319.4) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | PolyPhen probably damaging (0.925); catalogued as rs1176082000, COSV100604309; called by muse, mutect2, varscan2
- TTN | c.41975G>T p.G13992V (on ENST00000591111; = p.G6568V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | PolyPhen probably damaging (1); catalogued as COSV100604312, COSV60224458; called by muse, mutect2, varscan2
- TWNK | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs753457416, COSV99272240; called by muse, mutect2, varscan2
- UBE3A | c.820C>G p.H274D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99217016; called by muse, mutect2, varscan2
- USH2A | c.13380A>G p.I4460M | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1244395010, COSV100232571; called by muse, mutect2, varscan2
- VAV1 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100408879; called by muse, mutect2, varscan2
- VCAM1 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV99658389; called by muse, mutect2, varscan2
- WAPL | c.3531G>T p.Q1177H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); catalogued as COSV99556401; called by muse, mutect2
- WASHC5 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV59193995, COSV59194172; called by muse, mutect2, varscan2
- ZNF12 | c.991G>T p.G331W (on ENST00000405858 / NM_016265.4; = p.G293W on NM_006956.3) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703646; called by muse, mutect2, varscan2
- ZNF182 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV100526993, COSV59357666; called by muse, mutect2, varscan2
- ZNF184 | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.632); catalogued as COSV99279530; called by muse, mutect2, varscan2
- ZNF197 | c.1543T>C p.C515R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482037; called by muse, mutect2, varscan2
- ZNF257 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555293490, COSV71310222, COSV71312175, COSV71312346; called by muse, mutect2, varscan2
- ZNF296 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs113643466; called by muse, mutect2, varscan2
- ZNF443 | c.316A>G p.S106G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100042054; called by muse, mutect2, varscan2
- ZNF530 | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100252480; called by muse, mutect2, varscan2
- ZNF536 | c.2584G>T p.G862W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100834992; called by muse, mutect2, varscan2
- ZNF681 | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.122); catalogued as COSV101267432; called by muse, mutect2, varscan2
- ZNF804A | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.203); catalogued as COSV100167276; called by muse, mutect2, varscan2
- ZNF836 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV100440798; called by muse, mutect2, varscan2
- CNPY4 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by mutect2, varscan2
- IGHV1-45 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ILDR2 | c.277dup p.C93Lfs*35 | Frame Shift Ins (INS) | VAF 12/92 reads (13%) | called by mutect2, varscan2
- OR2F1 | c.677del p.L226Qfs*56 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- OR56A3 | c.711dup p.V238Rfs*32 | Frame Shift Ins (INS) | VAF 25/142 reads (18%) | called by mutect2, pindel, varscan2
- RP1 | c.3542C>G p.A1181G | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SERINC5 | c.1161_1177del p.Y388Pfs*? | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- SPIDR | c.213del p.I72Lfs*28 | Frame Shift Del (DEL) | VAF 41/231 reads (18%) | called by mutect2, pindel, varscan2
- SVEP1 | c.6408del p.M2137Cfs*17 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- A4GNT | c.933C>T p.L311= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV99367780; called by muse, mutect2, varscan2
- ACSBG1 | c.2028C>A p.P676= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99357241; called by mutect2, varscan2
- AHDC1 | c.3678G>A p.Q1226= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99899127; called by muse, mutect2, varscan2
- ANK2 | c.10044C>A p.L3348= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100000843, COSV52189247; called by muse, mutect2, varscan2
- AP002748.5 | c.1209C>G p.V403= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100567839; called by muse, mutect2, varscan2
- ATP2C1 | c.2184T>G p.P728= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100146561; called by muse, mutect2, varscan2
- AWAT1 | c.522C>A p.L174= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV100997193, COSV65738413; called by mutect2, varscan2
- BRINP3 | c.2004G>T p.V668= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100818619; called by muse, mutect2, varscan2
- CCDC92 | c.132G>C p.T44= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs750311683, COSV53019217, COSV99435415; called by muse, varscan2
- COL24A1 | c.969T>G p.S323= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV100993132; called by muse, mutect2, varscan2
- DNAH7 | c.9399G>A p.L3133= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV100414638; called by muse, mutect2, varscan2
- DOK5 | c.831C>T p.S277= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV52819675, COSV99373540; called by muse, mutect2, varscan2
- DPY19L1 | c.801A>G p.A267= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs756362968, COSV100204603; called by mutect2, varscan2
- ELAC2 | c.2046C>G p.L682= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV99310464; called by muse, mutect2, varscan2
- ELFN2 | c.1014C>T p.T338= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as COSV101297521; called by muse, mutect2, varscan2
- EPC1 | c.2373G>A p.L791= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV99552792; called by muse, mutect2, varscan2
- EPHB6 | c.2976G>A p.L992= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100844233; called by muse, mutect2, varscan2
- F13A1 | c.1653A>G p.T551= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99342681; called by muse, mutect2, varscan2
- FOXM1 | c.969G>A p.V323= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100700825; called by muse, mutect2, varscan2
- GBP3 | c.199C>T p.L67= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs752566632, COSV99352433; called by mutect2, varscan2
- GPR63 | c.1207C>A p.R403= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100013248, COSV100013486; called by mutect2, varscan2
- GUCY2C | c.2472A>G p.T824= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99663480; called by muse, mutect2, varscan2
- H2AW | c.351G>A p.L117= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100797267; called by muse, varscan2
- HDLBP | c.2226C>G p.L742= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV100190287; called by muse, varscan2
- HECW2 | c.2763C>G p.P921= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs781631738, COSV99646682; called by muse, mutect2, varscan2
- HOXA13 | c.858C>T p.N286= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs375188427, COSV56083894; called by mutect2, varscan2
- IGHV3OR16-8 | c.93A>T p.V31= | Silent (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- IGHV6-1 | c.129C>A p.A43= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- IGLC7 | c.291G>A p.E97= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- KLHDC4 | c.1506C>G p.G502= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV54507283, COSV99566263; called by muse, mutect2, varscan2
- KNTC1 | c.1824G>C p.V608= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100338162; called by muse, mutect2, varscan2
- KRT25 | c.753G>A p.L251= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100379877; called by muse, mutect2, varscan2
- LALBA | c.428G>A p.*143= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV99974376; called by muse, mutect2, varscan2
- MAMDC2 | c.1083C>A p.T361= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as rs771986746, COSV101015403; called by muse, mutect2, varscan2
- MARCHF11 | c.987C>T p.D329= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs764612045, COSV100197701; called by muse, mutect2, varscan2
- MCM2 | c.1869C>T p.R623= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99413006; called by muse, mutect2, varscan2
- MED12 | c.322C>A p.R108= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100377193; called by muse, mutect2, varscan2
- MRPL45 | c.273T>A p.P91= | Silent (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- MUS81 | c.1131C>G p.L377= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100337216; called by muse, mutect2, varscan2
- MYH10 | c.3771C>T p.L1257= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs780658326, COSV99344798; called by mutect2, varscan2
- NAT8 | c.306G>C p.L102= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99721970; called by muse, mutect2, varscan2
- NF1 | c.2983C>T p.L995= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV100646606; called by muse, mutect2, varscan2
- NR4A1 | c.774G>T p.G258= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs746689109, COSV99671183; called by muse, mutect2, varscan2
- OLFM4 | c.1407T>A p.I469= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs1566321607, COSV99524266; called by muse, mutect2, varscan2
- OPN4 | c.975C>T p.H325= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs199918331, COSV54119228, COSV99618209; called by muse, mutect2, varscan2
- OR10H2 | c.630C>G p.G210= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV100008714; called by muse, mutect2
- OR2M3 | c.516G>T p.R172= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as COSV101513416, COSV71759372; called by muse, mutect2, varscan2
- OR6C65 | c.687C>T p.A229= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV101110179; called by mutect2, varscan2
- OSM | c.6G>T p.G2= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99304104; called by muse, mutect2, varscan2
- PAPPA2 | c.3231G>C p.T1077= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as COSV62792179, COSV62811799; called by muse, mutect2, varscan2
- PAXBP1 | c.1743C>T p.S581= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs140333561; called by muse, mutect2, varscan2
- PCDH11X | c.4017C>A p.S1339= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV53445084; called by muse, mutect2, varscan2
- PCDHB5 | c.1614G>T p.P538= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV50657271, COSV99167804; called by muse, mutect2, varscan2
- PCLO | c.12651A>C p.S4217= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100430322; called by muse, mutect2
- PIK3CG | c.678C>G p.R226= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV100782772; called by muse, mutect2, varscan2
- PRICKLE3 | c.507G>T p.L169= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100889906; called by muse, mutect2, varscan2
- PRRG3 | c.276G>C p.L92= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV100948588; called by muse, mutect2, varscan2
- PTGER4 | c.459G>T p.L153= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV100201502; called by muse, mutect2, varscan2
- RAB5C | c.237A>T p.G79= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1420834435, COSV100651398; called by muse, mutect2, varscan2
- RAET1G | c.282G>C p.L94= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as COSV100951655, COSV66275194; called by muse, mutect2, varscan2
- RASGRF1 | c.2172C>T p.Y724= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs770172047, COSV101174436; ClinVar: likely benign; called by mutect2, varscan2
- REXO5 | c.1563G>A p.L521= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1158962182, COSV99759085; called by muse, mutect2, varscan2
- RP1 | c.5322C>A p.T1774= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99606985; called by mutect2, varscan2
- SCARA3 | c.1077C>A p.T359= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100106649; called by muse, mutect2, varscan2
- SLC6A11 | c.456A>T p.A152= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99594344; called by muse, mutect2, varscan2
- SLC7A3 | c.840C>A p.P280= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99979482; called by muse, mutect2, varscan2
- TEX10 | c.1462A>C p.R488= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV100887680; called by muse, mutect2, varscan2
- TMEM200C | c.1621C>A p.R541= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1280267248, COSV101274809, COSV67309191; called by muse, mutect2, varscan2
- TPR | c.1989A>G p.T663= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100823793; called by muse, mutect2, varscan2
- TTN | c.16755G>C p.G5585= (on ENST00000591111; = p.G4658= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/198 reads (12%) | catalogued as COSV100604316; called by muse, mutect2, varscan2
- UPB1 | c.24G>A p.S8= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs1172141022, COSV100387140, COSV58115011; called by muse, mutect2, varscan2
- USH2A | c.11124C>A p.P3708= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100232572; called by muse, mutect2, varscan2
- WDR17 | c.3783G>A p.V1261= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1358349674, COSV99707310; called by muse, mutect2, varscan2
- XKRX | c.765C>T p.L255= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100139634; called by muse, mutect2, varscan2
- ZNF331 | c.549G>T p.G183= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV53476025, COSV99467131; called by muse, mutect2, varscan2
- ZNF556 | c.699T>C p.C233= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100298678; called by muse, mutect2, varscan2
- ZNF665 | c.1590A>G p.E530= (on ENST00000600412; = p.E595= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV101128195; called by muse, mutect2, varscan2
- AL590867.2 | n.154T>C | RNA (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- DOCK8 | chr9:214811 C>T | 5'Flank (SNP) | VAF 7/13 reads (54%) | catalogued as rs751698019, COSV101213650; called by muse, mutect2, varscan2
- MAGEC3 | c.1729-55C>T | Intron (SNP) | VAF 10/71 reads (14%) | catalogued as rs891995647, COSV100025175; called by muse, mutect2, varscan2
- MIR196A1 | n.23G>T | RNA (SNP) | VAF 14/42 reads (33%) | catalogued as rs190478598; called by muse, varscan2
- N4BP2L2 | chr13:32442637 C>A | 3'Flank (SNP) | VAF 5/30 reads (17%) | called by muse, varscan2
- NEBL | c.164+25925A>G | Intron (SNP) | VAF 12/68 reads (18%) | catalogued as COSV101008760; called by muse, mutect2, varscan2
- RNF213 | c.3024+142G>T | Intron (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100173337, COSV100174021; called by mutect2, varscan2
- SNORD115-15 | n.67A>G | RNA (SNP) | VAF 44/271 reads (16%) | called by muse, mutect2, varscan2
- SSX7 | c.-2C>G | 5'UTR (SNP) | VAF 27/238 reads (11%) | catalogued as COSV99993792; called by muse, mutect2, varscan2
